Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5734, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5734-01A (Primary Tumor).

[page 1 of 2]
Findings and diagnosis in response to the question:

I) involves regular splenic tissue, divided into red and white pulp with the appropriate trabecular structure.

II) involves free fatty tissue and free lymph nodes.

III) involves a poorly differentiated advanced gastric carcinoma [REDACTED] in this case an invasive adenocarcinoma of the intestinal type, with infiltration of all wall layers (p T 2b), with extensive lymphatic vessel penetration (L 1 – [REDACTED] also below), with free resection margins in the mucosal area.

In addition, in eight cut surfaces there are lymph node metastases from the carcinoma described and, adjacent to these, indurated fatty connective tissue and infiltration of the omental tissue and partially also of the serosa (p T 3).

IV) involves regular anastomotic rings, here of the small bowel type with appropriate villous and crypt relief, lined with cylinder cells and goblet cells.

In respect of the pancreatic situation, further secondary resections will follow (p T 3 / p T 4).

[page 2 of 2]
A consultation was held about the definitive TNM classification.

This is defined by the infiltration of the omental tissue, in this case with infiltration of the peritoneum and, additionally to the initial findings, with infiltration of the lymph nodes in the area of the omentum in four cut surfaces.

In the pancreas these are inflammatory reactive changes.

The tumour classification is as follows:

ICDO-DA-M 8140/3

p T 3, p N 1, L 1.

In respect of the operative specimen a clear margin of healthy tissue was removed locally (cf. also where necessary the corresponding operative report).

Source: NCI Genomic Data Commons file fdcedf99-0f38-4785-901a-0a493a55d9e4 (TCGA-CG-5734.1C1ED591-33DC-4B7E-B2C2-9F3DB9307B2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).